Somatic mutation profile of tumor specimen TCGA-DU-6404-02B (aliquot TCGA-DU-6404-02B-11D-A36O-08) from TCGA case TCGA-DU-6404, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 24.7 years (9,021 days).
Specimen TCGA-DU-6404-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cab74a5-4358-4fff-a5b5-32145746fc51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6404-10A (Blood Derived Normal), aliquot TCGA-DU-6404-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b84b7ff-d5fd-4a8f-a4e7-2bf7908689cc

The open-access MAF lists 98 somatic variants for this specimen: 72 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 23, Frame Shift Del 4, Intron 2, Nonsense Mutation 2, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.14110C>T p.R4704* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as rs1568595930, COSV100616083; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2429T>C p.L810S (on ENST00000272895 / NM_173076.3; = p.L492S on NM_015657.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99790534; called by muse, mutect2, varscan2
- ABCA13 | c.2308A>G p.I770V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs779948240, COSV101330092; called by muse, mutect2
- ADAM10 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV99546210; called by muse, mutect2, varscan2
- ADAMTS12 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100711178; called by muse, mutect2, varscan2
- ADD1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767055661, COSV53271278; called by muse, mutect2, varscan2
- ADGRG7 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as rs552262431, COSV99841177; called by muse, mutect2
- ADGRV1 | c.7303C>T p.P2435S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV101316125; called by muse, mutect2, varscan2
- AFF4 | c.2277A>T p.K759N | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99535062; called by muse, mutect2, varscan2
- ASAP2 | c.1023C>T p.T341= | Splice Region (SNP) | VAF 25/55 reads (45%) | catalogued as rs143591778, COSV99856167; called by muse, mutect2, varscan2
- ATP13A1 | c.1685G>A p.S562N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1346352574, COSV99366299; called by muse, mutect2, varscan2
- BCAN | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228213; called by muse, mutect2
- BRCA1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100524459; called by muse, mutect2, varscan2
- C1orf116 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1383767242, COSV100847954; called by muse, mutect2, varscan2
- C5AR2 | c.761T>A p.L254Q | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99953788; called by muse, mutect2, varscan2
- CARMIL1 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.944); catalogued as rs747633709; called by muse, mutect2
- CDH23 | c.5932C>A p.L1978I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV99821803; called by muse, mutect2, varscan2
- CDHR5 | c.1867G>A p.G623S (on ENST00000358353 / NM_001171968.2; = p.G629S on NM_021924.5) | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.972); catalogued as rs140290184, COSV57642492; called by muse, mutect2, varscan2
- CDKL5 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV101184378; called by muse, mutect2, varscan2
- CLCN1 | c.1613A>G p.H538R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100578164; called by muse, mutect2, varscan2
- CREBBP | c.4231G>C p.G1411R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52118491, COSV52144101; called by muse, mutect2, varscan2
- CUL5 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1344812542, COSV101263702; called by muse, mutect2
- DLG5 | c.3376G>T p.V1126L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100967582; called by muse, mutect2, varscan2
- EMC7 | c.561T>A p.D187E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99854893; called by muse, mutect2, varscan2
- EMP1 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV99916973; called by muse, mutect2, varscan2
- FASN | c.2792T>C p.V931A | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100147951; called by muse, mutect2, varscan2
- FPR1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs145808420; called by muse, mutect2, varscan2
- GANAB | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100648090; called by muse, mutect2, varscan2
- HECW2 | c.4601T>C p.L1534P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647578; called by muse, mutect2, varscan2
- HHIPL2 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752581216, COSV100596929; called by muse, mutect2, varscan2
- HTR3A | c.744C>A p.S248R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs1218620531, COSV100248479; called by muse, mutect2, varscan2
- KCTD17 | c.844G>A p.A282T (on ENST00000403888 / NM_001282684.1; = p.A258T on NM_024681.3) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1157809169, COSV100695907, COSV60982316; called by muse, mutect2, varscan2
- KIAA1841 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693862; called by muse, mutect2, varscan2
- KRT82 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99233710; called by muse, mutect2, varscan2
- LRBA | c.3138T>G p.D1046E | Missense Mutation (SNP) | VAF 72/73 reads (99%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100841779; called by muse, mutect2, varscan2
- M6PR | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780103335, COSV99134088; called by muse, mutect2, varscan2
- MACF1 | c.10442A>G p.E3481G | Missense Mutation (SNP) | VAF 14/16 reads (88%) | catalogued as COSV99245216; called by muse, mutect2, varscan2
- MGAM | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1450690513, COSV101516454; called by muse, mutect2, varscan2
- MTA1 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100495250; called by muse, mutect2, varscan2
- MYH9 | c.2605A>C p.T869P | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99069928, COSV99339154; called by muse, mutect2, varscan2
- NFATC3 | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV100285348; called by muse, mutect2
- NLRP8 | c.3059C>A p.A1020D | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99405451; called by muse, mutect2, varscan2
- PCDHB3 | c.2315C>A p.P772H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1554272718, COSV99165527; called by muse, mutect2, varscan2
- PCDHGA2 | c.2195T>A p.L732* | Nonsense Mutation (SNP) | VAF 65/124 reads (52%) | catalogued as COSV99540654; called by muse, mutect2, varscan2
- PGAP1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as COSV100698242; called by muse, mutect2, varscan2
- PIK3R6 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100266606; called by muse, mutect2, varscan2
- PIWIL3 | c.2644C>G p.L882V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100177733; called by muse, mutect2, varscan2
- PPOX | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99237529; called by muse, mutect2, varscan2
- PRIM1 | c.822A>T p.K274N | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100590415; called by muse, mutect2, varscan2
- PRPH | c.916C>A p.R306S | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99142010; called by muse, mutect2, varscan2
- PTCRA | c.65del p.G22Afs*146 | Frame Shift Del (DEL) | VAF 21/40 reads (53%) | catalogued as COSV100485763; called by mutect2, pindel, varscan2
- RAB4B | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV100826442; called by muse, mutect2, varscan2
- RASGRP1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370888491; called by muse, mutect2, varscan2
- RFTN1 | c.347A>T p.D116V | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as COSV100489517; called by muse, mutect2, varscan2
- SCN11A | c.1705G>T p.V569F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1346252289, COSV100181815; called by muse, mutect2, varscan2
- SDK1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV101269521; called by muse, mutect2
- SLFN11 | c.1300T>G p.F434V | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100390733; called by muse, mutect2, varscan2
- SMARCE1 | c.1097A>G p.D366G | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99228404; called by muse, mutect2, varscan2
- SPP1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated (0.14); PolyPhen benign (0.411); catalogued as rs757338944, COSV52951625; called by muse, mutect2, varscan2
- SSTR3 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100142710; called by muse, mutect2
- TBXAS1 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV104375066, COSV99695527; called by muse, mutect2
- TIGD2 | c.382C>G p.R128G | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100392389, COSV57647357; called by muse, mutect2, varscan2
- TLN2 | c.3688-2A>T p.X1230_splice | Splice Site (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100169326; called by muse, mutect2, varscan2
- TM4SF20 | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100460102; called by muse, mutect2
- TNRC18 | c.5339G>A p.R1780K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV101269636, COSV101269718; called by muse, mutect2, varscan2
- YME1L1 | c.2180A>G p.D727G (on ENST00000326799 / NM_139312.3; = p.D670G on NM_014263.4) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100463819; called by muse, mutect2, varscan2
- ZFHX3 | c.9965A>G p.Q3322R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs866111931, COSV99213377; called by muse, mutect2, varscan2
- ZNF354B | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100483043; called by muse, mutect2, varscan2
- GANAB | c.1480del p.D494Mfs*24 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- PCDHB2 | c.2321C>A p.P774H | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- PSME4 | c.2237del p.P746Lfs*69 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- ZNF280C | c.345_369del p.Q116Rfs*43 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel
- CTNNAL1 | c.1413G>A p.E471= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100336615, COSV100336694; called by muse, mutect2, varscan2
- CTSG | c.537C>T p.Y179= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1476151995, COSV53535132; called by muse, mutect2, varscan2
- DHX35 | c.1753T>C p.L585= | Silent (SNP) | VAF 87/160 reads (54%) | catalogued as COSV99326985; called by muse, mutect2, varscan2
- DHX9 | c.1149G>A p.Q383= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs753345547, COSV100841446; called by muse, mutect2, varscan2
- DPF3 | c.250C>A p.R84= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs764426480, COSV100818531, COSV100818605; called by muse, mutect2, varscan2
- EVI5L | c.156C>G p.S52= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99563273; called by muse, mutect2, varscan2
- FAM20A | c.918T>C p.F306= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as CD132167, COSV99873370; called by muse, mutect2, varscan2
- FAT1 | c.7290G>C p.L2430= | Silent (SNP) | VAF 58/59 reads (98%) | catalogued as COSV101499419; called by muse, mutect2, varscan2
- FBN1 | c.4740G>C p.V1580= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100355557; called by muse, mutect2, varscan2
- HDLBP | c.1908C>T p.C636= | Silent (SNP) | VAF 63/118 reads (53%) | catalogued as rs187198864, COSV60497530; called by muse, mutect2, varscan2
- LRP6 | c.150G>A p.L50= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV99743609; called by muse, mutect2, varscan2
- MUC16 | c.6477T>C p.L2159= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV101200258; called by muse, mutect2, varscan2
- NLRP8 | c.3060C>G p.A1020= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV99405453; called by muse, mutect2, varscan2
- NOL4L | c.993C>T p.Y331= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs765215561, COSV62889363; called by muse, varscan2
- OOSP2 | c.181C>A p.R61= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV53928154, COSV53928565; called by muse, mutect2, varscan2
- PIK3C2B | c.2565G>C p.L855= | Silent (SNP) | VAF 81/120 reads (68%) | catalogued as COSV100916160; called by muse, mutect2, varscan2
- RTL9 | c.2559A>T p.T853= | Silent (SNP) | VAF 86/202 reads (43%) | catalogued as COSV101511717; called by muse, mutect2, varscan2
- SERPINI2 | c.222T>A p.T74= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV52989081, COSV99248040; called by muse, mutect2, varscan2
- SIGLEC6 | c.228G>T p.V76= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100585494; called by muse, mutect2, varscan2
- SKOR1 | c.2571C>A p.I857= | Silent (SNP) | VAF 73/132 reads (55%) | catalogued as rs377094576, COSV58249964; called by muse, mutect2, varscan2
- SSMEM1 | c.390G>A p.R130= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99927754; called by muse, mutect2, varscan2
- SSU72P8 | c.552A>G p.G184= | Silent (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2
- VPS52 | c.690C>T p.L230= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs751974793, COSV101460439; called by muse, mutect2, varscan2
- AK5 | c.699+15887G>C | Intron (SNP) | VAF 8/8 reads (100%) | catalogued as COSV100481512, COSV100481578; called by muse, mutect2, varscan2
- BCAS3 | c.2075-4654A>T | Intron (SNP) | VAF 12/121 reads (10%) | catalogued as COSV101176202; called by muse, mutect2, varscan2
- MYADM | chr19:53874369 C>G | 3'Flank (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100425107, COSV61239143; called by muse, mutect2, varscan2
